Gene-level copy-number profile of tumor specimen TCGA-AP-A0LH-01A from TCGA case TCGA-AP-A0LH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.7 years (22,169 days).
Specimen TCGA-AP-A0LH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.8ca813fc-8942-458b-a9ab-544acbe0d06c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A0LH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/530772e7-e790-4fee-92c9-5b3c0a71c4c0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,846; copy number 2: 49,720; copy number 3: 5,315; copy number 4: 851; copy number 5: 27; copy number 6: 12; copy number 8: 2; copy number 11: 21; copy number 14: 1; copy number 16: 7; copy number 22: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A0LH-01A-11D-A042-01): tumor purity 0.93, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 85 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,493,515–117,495,006, 1 gene, copy number 5: AL157902.2.
- chr1:205,302,063–205,680,509, 15 genes, copy number 5 (within-gene range 3–5): NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3.
- chr1:209,147,220–209,266,758, 1 gene, copy number 5 (within-gene range 3–5): AC092810.2.
- chr1:209,232,196–209,567,673, 8 genes, copy number 5 (within-gene range 3–5): TFDP1P1, ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2.
- chr2:185,738,804–185,833,290, 1 gene, copy number 6 (within-gene range 2–6): FSIP2.
- chr5:45,254,948–45,895,970, 4 genes, copy number 6: HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:117,287,120–117,715,971, 1 gene, copy number 6 (within-gene range 2–6): CFTR.
- chr7:117,439,982–117,647,415, 5 genes, copy number 6: ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 8: AC139365.2, AC139365.1.
- chr12:37,575,587–37,576,384, 1 gene, copy number 6: ZNF970P.
- chr16:61,691,756–61,743,476, 2 genes, copy number 5: AC092125.1, RN7SKP76.
- chr19:28,683,071–30,957,192, 44 genes, copy number 11–22 (within-gene range 3–22): AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.

Autosomal genes at a single copy (total copy number 1): 3,846. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
